TCGA case TCGA-BR-6706 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/93aebbd4-19cf-495a-b8ce-3c4a3feba152

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 63 years; Vital status: Dead; Days to death: 549 days (1.5 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.0; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 63.1 years (23,053 days); Year of diagnosis: 2010; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 5; Lymph nodes tested: 15.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide + Fluorouracil + Leucovorin; Days to treatment start: 56 days; Days to treatment end: 147 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin; Days to treatment start: 402 days (1.1 years); Days to treatment end: 445 days (1.2 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 402 days (1.1 years); Days to treatment end: 410 days (1.1 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 441 days (1.2 years); Days to treatment end: 445 days (1.2 years).
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Adenocarcinoma, NOS), site: Peritoneum, NOS. Age at diagnosis: 64.2 years (23,455 days); Days to diagnosis: 402 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Days to follow up: 66 days; Disease response: Tumor Free.
- Day 402 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Peritoneum, NOS; Days to recurrence: 402 days (1.1 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 549 days (1.5 years); Disease response: With Tumor.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-6706-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.5; Intermediate dimension: 1.7; Shortest dimension: 0.6.
  Slide TCGA-BR-6706-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20.
  Slide TCGA-BR-6706-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15.
- Sample TCGA-BR-6706-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-6706-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-BR-6706-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.2; Intermediate dimension: 1.4; Shortest dimension: 0.6.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Anatomic organ subdivision: Cardia/Proximal; Lymph nodes examined: Yes; Cancer procurement city: Kiev.
- Drug treatment 1: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Follow-up form 1: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 1, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form 1, New neoplasm event types: New tumor event type: Locoregional Recurrence.
- Follow-up form 2: Lost to follow-up: No; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; New tumor event site: Peritoneal Surfaces; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Progressive Disease; Cause of death: Stomach Cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 549 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 549 days; disease-free interval: event (new tumor event after initially disease-free), 402 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 402 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-6706-01A-11D-1881-01): tumor purity 0.23, ploidy 2.11, whole-genome doublings 0.
